Somatic mutation profile of tumor specimen 0DQMPO from CCDI case PBCESA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.1 years (1,864 days).
Specimen 0DQMPO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d426f05b-208e-4930-8987-00f4296cdb3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQMQU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c9009ed-c288-4c09-9324-361f4f61eda0

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 279/707 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2
- LPAR1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 768/1644 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.417); catalogued as COSV62687199; called by muse, mutect2, varscan2
- MAD2L1BP | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 209/645 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs770277022; called by muse, mutect2, varscan2
- TMEFF1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 56/952 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV100614597; called by muse, mutect2
- ASXL1 | c.2113dup p.E705Gfs*13 | Frame Shift Ins (INS) | VAF 76/160 reads (48%) | called by mutect2, varscan2
- CYP2S1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 111/246 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OBSL1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH12 | c.1128C>A p.V376= | Silent (SNP) | VAF 24/600 reads (4%) | catalogued as COSV51521608; called by muse, mutect2
- PDE6C | c.1521C>T p.Y507= | Silent (SNP) | VAF 80/1018 reads (8%) | catalogued as rs746197485, COSV101008842; called by muse, mutect2
- SLC7A2 | c.1590C>T p.L530= (on ENST00000494857 / NM_001370338.1; = p.L569= on NM_003046.6) | Silent (SNP) | VAF 311/687 reads (45%) | catalogued as rs772415857, COSV99136473; called by muse, mutect2, varscan2
- TMC1 | c.2178G>A p.A726= | Silent (SNP) | VAF 531/1242 reads (43%) | catalogued as rs555517698, COSV52772402; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR6C3 | chr12:55331695 C>T | 5'Flank (SNP) | VAF 122/262 reads (47%) | catalogued as rs750849246; called by muse, mutect2, varscan2
- SLC17A3 | c.598-35G>A | Intron (SNP) | VAF 50/562 reads (9%) | catalogued as rs373994029; called by muse, mutect2
- SLC1A5 | c.-88C>T | 5'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
